Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAL6, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAL6-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchidectomy; nonseminoma (EC 95 %, YST 5%, scattered trophoblastic giant cells);
diameter 4 cm; angio-invasion present; no invasion of rete testis; tumor confined to testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3
Carcinoma, embryonal 9876/3
Site: B Testis NOS C62.9
QW 3/5/14

Source: NCI Genomic Data Commons file b129fa42-a688-4ccf-afcd-4af3ef16012c (TCGA-2G-AAL6-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).